Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3359, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3359-01A (Primary Tumor).

[page 1 of 2]
Collected Date & Time: [REDACTED]

Result Name	Results	Units	Reference Range
☒ Surgical Pathology	COPY TO:		

COPY TO:

Pre-Op Diagnosis

Left renal tumor

Post-Op Diagnosis

Same as above

Clinical History

Nothing indicated

Gross Description:

Received in a single container labeled [REDACTED] - left kidney" is a 222 gram previously partially sectioned left nephrectomy specimen surrounded by a moderate amount of edematous perinephric adipose tissue. The specimen as received measures 15.1 x 8.5 x 5.1 cm. The margins of resection include 2.0 cm of grossly patent renal artery, 1.0 cm of grossly patent renal vein, and 5.5 cm of grossly patent ureter. The capsule strips with moderate ease to reveal an organ measuring 11.0 x 6.0 x 5.6 cm. The cortex is slightly pale, lobulated, granular and tan brown. On the anterior aspect in the upper pole extending toward the mid region is a 4.0 x 4.0 x 3.6 cm lobulated tan gray to yellow well circumscribed unencapsulated nodular lesion which extends beyond the plane of the kidney but appears to be completely encased by the renal capsule. This has a slightly bulging fleshy focally hemorrhagic tan yellow cut surface. The lesion appears to compress the surrounding structures but does not appear to grossly extend into them. The remaining cortex is up to 0.5 cm, homogeneous, slightly granular and tan brown. The cortical medullary junction is poorly defined. The medulla is tan pink with sharp papillae. The calyces and pelvis are lined by smooth gray white mucosa extending into the ureter. The adrenal gland is not grossly identified. Also received in the same container are three tissue cassettes each labeled [REDACTED]. Representative sections are submitted labeled as follows: A - vascular and ureteral margins; B through F - representative lesion and surrounding tissue; G - random uninvolved parenchyma.

Microscopic Description:

The slides labeled [REDACTED] are examined. See diagnosis.

Final Diagnosis

Left kidney (nephrectomy):

Tumor:

Histologic type: Renal cell carcinoma (clear cell type).

Tumor site: Upper pole.

Tumor size: 4.0 cm in greatest diameter.

Macroscopic extent of tumor: Tumor limited to kidney.

Nuclear grade: Fuhrman grade 2/3

Lymphovascular space invasion: No unequivocal lymphovascular space invasion identified.

Transcapsular invasion: No

Renal vein invasion: No

Vena caval invasion: Not resected

Adrenal gland: Not resected.

Surgical margin status:

Soft tissue margins: Not involved

Ureteral surgical margins: Not involved

Vascular surgical margins: Not involved

Lymph node status: No lymph nodes resected. PAS 9

Other findings:

Interstitial chronic inflammation. PAS 6 SPC-A

CPT: 88307 x 1

Comments

[page 2 of 2]
This test has been finalized at the [REDACTED] Campus.
[REDACTED]

Source: NCI Genomic Data Commons file d405b873-04e5-41ff-81c1-9e7cdaf91946 (TCGA-A3-3359.C2950EF2-5E99-40EC-81AD-B6127A32E357.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).